Somatic mutation profile of tumor specimen TARGET-20-PARVUA-03A (aliquot TARGET-20-PARVUA-03A-01D) from TARGET case TARGET-20-PARVUA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.8 years (5,786 days).
Specimen TARGET-20-PARVUA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 860c8e53-11f4-4566-a865-8816bb985c69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVUA-14A (Bone Marrow Normal), aliquot TARGET-20-PARVUA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b345ff2c-4b3a-46e2-8baf-99e5413e31e4

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSS | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs750405485, COSV53811666; called by muse, varscan2
- MYH11 | c.5000C>T p.S1667F | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1345711998, COSV55544865; called by muse, mutect2, varscan2
- FTL | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- PCDHAC1 | c.2599G>A p.V867M | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by mutect2, varscan2
